Gene-level copy-number profile of tumor specimen C3L-07629-02 from CPTAC case C3L-07629, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 62.2 years (22,717 days).
Specimen C3L-07629-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7b4ca366-811f-4f93-979a-e8d5f10ceca4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07629-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/22ed0b9b-efd9-4b79-b2f0-20581fc12a65

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 9,461; copy number 2: 33,813; copy number 3: 13,173; copy number 4: 1,368; copy number 5: 263; copy number 6: 22; copy number 7: 3; copy number 10: 39; copy number 11: 64; copy number 12: 90; copy number 14: 1; copy number 15: 37; copy number 16: 13; copy number 18: 9; copy number 20: 9; copy number 21: 5; copy number 40: 6; copy number 140: 3; copy number 293: 2; copy number 380: 5.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,936,079–8,963,077, 1 gene (within-gene range 0–1): AL596451.1.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–1): RN7SL5P.
- chr15:26,395,037–26,970,385, 8 genes: LINC02248, AC009878.2, GABRB3, AC009878.1, AC011196.1, AC135999.1, GABRA5, TVP23BP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 571 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,173,056–1,630,610, 44 genes, copy number 5: TTLL10-AS1, TTLL10, TNFRSF18, TNFRSF4, SDF4, B3GALT6, C1QTNF12, AL162741.1, UBE2J2, LINC01786, SCNN1D, ACAP3, MIR6726, PUSL1, INTS11, MIR6727, AL139287.1, CPTP, TAS1R3, DVL1, MIR6808, MXRA8, AURKAIP1, NDUFB4P8, CCNL2, MRPL20-AS1, MRPL20, RN7SL657P, MRPL20-DT, ANKRD65, AL391244.1, TMEM88B, LINC01770, VWA1, ATAD3C, ATAD3B, ATAD3A, TMEM240, SSU72, AL645728.1, AL691432.3, FNDC10, AL691432.2, MIB2.
- chr6:37,482,938–44,450,425, 192 genes, copy number 5–15 (broad region; genes not listed).
- chr7:54,419,444–55,433,742, 16 genes, copy number 40–380: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr9:61,865,755–63,385,117, 45 genes, copy number 5: AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4, BMS1P10, AQP7P1, AL845321.1.
- chr9:65,282,101–65,573,495, 3 genes, copy number 7: FOXD4L5, CBWD4P, Y_RNA.
- chr9:66,253,424–70,414,624, 73 genes, copy number 10–20 (broad region; genes not listed).
- chr9:71,589,601–76,651,203, 57 genes, copy number 5–15 (within-gene range 4–15): RPL35AP21, CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1, DPP3P2, AL451127.1, AL512594.1, RNA5SP286, AL513124.1, AL355674.1, RORB-AS1, RORB, AL137018.1, TRPM6, RN7SKP47, RPSAP75, RNU6-445P, AL158825.1, C9orf40, CARNMT1-AS1, CARNMT1, AL158825.2, AL158825.3, NMRK1, OSTF1, Y_RNA, RNU6-1228P, AL158073.1, AL353780.1, OTX2P1, PCSK5, RBM22P5, RFK, RPSAP9, GCNT1, H3P32.
- chr12:30,169,881–30,296,707, 3 genes, copy number 6: AC023511.2, AC023511.1, LINC02386.
- chr12:31,105,105–34,249,958, 84 genes, copy number 5 (broad region; genes not listed).
- chr13:57,991,350–57,991,464, 1 gene, copy number 5: RNA5SP30.
- chr13:81,018,176–81,302,407, 6 genes, copy number 16: LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2.
- chr20:52,671,735–53,827,297, 18 genes, copy number 6–21: AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1.
- chr20:63,895,126–63,936,031, 1 gene, copy number 5 (within-gene range 2–5): DNAJC5.
- chr20:63,919,449–64,327,972, 28 genes, copy number 5: MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 7,117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
